Surgical pathology report (de-identified scan), TCGA case TCGA-HM-A3JK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-HM-A3JK-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Uterus, cervix, endomyometrium, parametria and upper vagina, hysterectomy:

Squamous cell carcinoma of the cervix, poorly differentiated, with direct extension into uterine wall, parametrial and upper vaginal tissues, size of mass 4.8 cm.

Surgical margins uninvolved.

Ovaries, right and left, resection:

No carcinoma identified.

Fallopian tubes, right and left, resection:

No carcinoma identified.

B. Right pelvic lymph nodes, resection:

Metastatic squamous cell carcinoma in one of 23 lymph nodes (1/23).

C. Left pelvic lymph nodes, resection:

No carcinoma seen in 16 lymph nodes (0/16).

D. Periaortic lymph nodes, resection:

No carcinoma seen in 12 lymph nodes (0/12).

Microscopic Description:

Microscopic examination performed.

A. Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT) TNM (FIGO): Carcinoma involves all sections of the cervix with direct extension into the myometrial wall, parametrial tissues and upper vagina. pT2b. IIB

Margins of resection: uninvolved

Vascular invasion: Not identified

Regional lymph nodes (pN): Metastatic carcinoma is present in one node as described below pN1

Distant metastasis (pM): Cannot be evaluated by the specimen, pMX

Other findings: None

B. Sections of the right pelvic lymph nodes demonstrate metastatic carcinoma involving 1 of 23 nodes.

C. Sections of the left pelvic lymph nodes demonstrate no evidence of metastasis in 16 lymph nodes.

D. Sections of the periaortic lymph nodes demonstrate no evidence of metastasis in 12 lymph nodes.

Specimen

A. Uterus, cervix, tubes, ovaries, bilateral parametria and upper vagina

B. Right pelvic lymph nodes

C. Left pelvic lymph nodes

D. Periaortic lymph node

Clinical Information

Cervical cancer

ICD-0-3
carcinoma, squamous cell 8070/3
Site: Cervix, NOS C53.9
pw
12/8/11

[page 2 of 2]
Gross Description

A. Container A is labeled with the patient's name, medical record number and "uterus, cervix, tubes, ovaries, bilateral parametria and upper vagina". The specimen consists of a uterus with attached bilateral adnexa and parametria. The uterus measures 8.9 cm from the tip of the cervix to the top of the fundus, 4.8 cm in breadth and 4.2 cm in width. The external examination of the ectocervix demonstrates a tan firm tumor nodule occupying the majority of the mucosal surface. The uterus is bivalved, and the uterine cervix contains a fungating tumor mass with direct extension into the myometrial wall. The overall dimensions of the tumor including both involvement of cervix and uterine corpus it is 4.8 x 4.0 x 2.5 cm. Tumor additionally grossly involve the parametrial tissue and upper vagina bilaterally. The endometrial surface is focally ulcerated by involvement from the tumor.

The ovaries bilaterally are grossly uninvolved by tumor and average 1.2 x 0.8 x 0.5 cm. Fallopian tube segments are unremarkable. Rep. sections submitted. BLOCK SUMMARY: A1-A13: Entire cervix and adjacent parametrial tissue, upper vagina, submitted from 12 to 11:00., A 14, A:15 - lower uterine segment, A16 - A18 representative sections of myometrial wall, involved by tumor, a 19, 820 - bilateral ovaries and fallopian tubes.

B. Received in formalin labeled "right pelvic lymph nodes" are multiple yellow lobular fatty tissue fragment having an aggregate measurement of 7.5 x 7.0 x 2.5 cm. The specimens are palpated to identify possible lymphoid tissue the lymph nodes range from 0.3 cm to 4.5 cm in greatest dimension. The lymph nodes are entirely submitted as follows: 1 - 4 possible lymph nodes, 2 - 6 possible lymph nodes, 3 - 2 possible lymph nodes, 4 - one possible lymph node bisected, 5/6 - one possible lymph node bisected, one half in each, 7 through 11 - one possible lymph node sectioned, 12 through 17 - one possible lymph node sectioned RS 17

C. Received in formalin labeled "left pelvic lymph node" are multiple yellow lobular fatty tissue fragments which have an aggregate measurement 7.5 x 5.5 x 3.5 cm. The specimens are palpated to identify multiple lymph nodes which range from 0.5 cm and 3.5 cm in greatest dimension. The lymph node are entirely submitted as follows: 1 - 4 possible lymph nodes, 2 - 3 possible lymph nodes, 3 - 2 possible lymph nodes, 4 - 2 possible lymph nodes, 5 - 4 possible lymph nodes, - one possible lymph node bisected, 7 - one possible lymph node bisected, 8/9 - one possible lymph node bisected, one half in each, 10/11 - one possible lymph node bisected, one half in each. RS 11

D. Received in in formalin labeled "periaortic lymph nodes" are multiple yellow lobular fatty tissue fragments which have an aggregate measurement of 5.5 x 4.5 and 1.2 cm. The specimens are palpated to identify multiple lymph nodes which range from 0.5 cm a 2.5 cm in greatest dimension. The lymph nodes are entirely submitted as follows: 1 - 4 possible lymph nodes, 2 - 4 possible lymph nodes, 3 - one possible lymph node bisected, or - one possible lymph node bisected, 5 - one possible lymph node bisected, 6/7 - one possible lymph node bisected, one half in each. RS 7

Source: NCI Genomic Data Commons file 5c3caee1-b8a8-41e4-bafe-460038684041 (TCGA-HM-A3JK.4CB35553-A72C-474B-A9EB-27EE44173A84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).